Somatic mutation profile of tumor specimen TCGA-EJ-7317-01A (aliquot TCGA-EJ-7317-01A-31D-2114-08) from TCGA case TCGA-EJ-7317, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.4 years (26,064 days).
Specimen TCGA-EJ-7317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e9ff178-643d-416a-924c-56ae8050969f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7317-10A (Blood Derived Normal), aliquot TCGA-EJ-7317-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/436f6432-b464-4b6a-8514-bfe31f0d7ef7

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 21, Silent 12, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.833+1G>T p.X278_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV55459394; called by muse, mutect2, varscan2
- BCR | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV59936009; called by muse, mutect2, varscan2
- CCDC88A | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV55062188, COSV55070536; called by muse, mutect2, varscan2
- CDHR2 | c.3104C>A p.T1035N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56145793; called by muse, mutect2
- CFAP43 | c.4372T>C p.Y1458H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63855063; called by muse, mutect2, varscan2
- CFAP92 | c.708del p.E236Dfs*80 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV54049268; called by mutect2, pindel
- CRYBG3 | c.7913G>C p.C2638S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); catalogued as COSV51716340; called by muse, mutect2, varscan2
- CSMD3 | c.10469T>C p.V3490A (on ENST00000297405 / NM_001363185.1; = p.V3321A on NM_052900.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52326919; called by muse, mutect2
- FRYL | c.4662G>A p.W1554* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | catalogued as COSV51963084; called by muse, mutect2, varscan2
- GIMAP1 | c.299A>C p.E100A | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV56189856, COSV56189864; called by muse, mutect2, varscan2
- GIT2 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.27); catalogued as rs773484065, COSV58085045; called by muse, mutect2, varscan2
- H2BC15 | c.212T>G p.F71C | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57584724, COSV57586623; called by muse, mutect2, varscan2
- IPO13 | c.592T>G p.C198G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV64895145; called by muse, mutect2
- ITGAL | c.2733C>G p.N911K | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63324503; called by muse, mutect2, varscan2
- KRT78 | c.919A>C p.K307Q | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV58853890; called by muse, mutect2, varscan2
- PCDH15 | c.4259C>A p.P1420H | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57268201; called by muse, varscan2
- PPWD1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54335764; called by muse, mutect2, varscan2
- RYR2 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375935636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4C | c.853T>C p.C285R | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59692389; called by muse, mutect2
- TMEM139 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV60083683; called by muse, mutect2, varscan2
- UGT2B7 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV59441838, COSV59445585; called by muse, mutect2, varscan2
- WDR24 | c.2707C>G p.L903V (on ENST00000248142; = p.L773V on NM_032259.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV50205328; called by muse, mutect2
- ZC3H12D | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66325201; called by muse, mutect2
- ZNF773 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV56590554; called by muse, mutect2, varscan2
- KDM6A | c.4138del p.M1380Wfs*4 | Frame Shift Del (DEL) | VAF 55/95 reads (58%) | called by mutect2, pindel, varscan2
- ATP6V0B | c.570G>C p.G190= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs1393761885, COSV52545424; called by muse, mutect2, varscan2
- CCN5 | c.684G>A p.Q228= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV51939481; called by muse, mutect2, varscan2
- CCNB1 | c.885T>C p.F295= | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV56511104; called by muse, mutect2
- CENPE | c.7239G>A p.V2413= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54390836; called by muse, mutect2, varscan2
- DNAH5 | c.11550A>G p.L3850= | Silent (SNP) | VAF 9/199 reads (5%) | catalogued as COSV54253608; called by muse, mutect2
- KIF20A | c.1737G>A p.Q579= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as rs114549959, COSV67510689; called by muse, mutect2, varscan2
- PCARE | c.1776G>A p.T592= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs201520631, COSV59054616; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH15 | c.4260C>G p.P1420= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV57377850, COSV57398752, COSV57406684; called by muse, varscan2
- PCDHB10 | c.576A>G p.P192= | Silent (SNP) | VAF 98/312 reads (31%) | catalogued as COSV53384154; called by muse, mutect2, varscan2
- PDGFRL | c.105G>A p.E35= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV52415394; called by muse, mutect2
- TOPORS | c.591T>G p.G197= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV62118338; called by muse, mutect2, varscan2
- ZNF217 | c.1014G>A p.K338= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs778395073, COSV56602751; called by muse, mutect2, varscan2
